Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6B9, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6B9-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with large cystic and solid abdominal mass (22x11x 18 cm). IR biopsy favors smooth muscle neoplasm.

Specimens Submitted:

- 1: Radical resection of abdominal mass with resection of splenic flexure of colon
- 2: Umbilical hernia

DIAGNOSIS:

1. Abdominal mass and splenic flexure of colon; radical resection:
- Leiomyosarcoma, low grade, involving colonic subserosa, see note.
- The tumor measures 15.0 x 11.5 x 6.5 cm.
- Mitotic activity: 2 mitotic figures per 50 high power (40X) fields.
- Necrosis is not identified.
- Unremarkable colonic mucosa.
- The surgical margins are uninvolved by tumor.
- Fifteen benign lymph nodes (0/15).

Note: The tumor is present in the subserosa, however, the tumor makes contact with the muscularis propria. Thus, it is difficult to determine if the tumor arises from the muscularis. The tumor displays multiple foci with moderate to severe nuclear atypia and pleomorphism that do not appear to be degenerative in nature. Immunohistochemical stains show that the tumor cells are positive for PR and negative for ER. MIB-1 staining reveals a proliferative index of approximately 2% with labeling of cells with large, atypical nuclei. Expression of PR raises the possibility of an origin in the gynecologic tract. This case was reviewed in consultation with

2. Umbilical hernia; excision:
- Benign fibroadipose tissue with mesothelial lining and reactive changes.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is

** Continued on next page **

ICD-O-3

Leiomyosarcoma 8890/3
Site C6CF Retroperitoneum
path C49.8
Connective, subcutaneous
and other soft tissues of
the abdomen C49.4
JW 5/21/13

[page 2 of 3]
----- Page 2 of 3
not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "radical resection of abdominal mass with resection of splenic flexure of colon," and consists of a segment of large bowel measuring 12.5 cm in length and 2.5 cm in average diameter with a subserosal solid and cystic mass that measures 15 x 11.5 x 6.5 cm. The attached mesocolon measures 12 x 6 x 1 cm. The mass is sectioned to reveal a solid component that displays heterogeneous, tan-white, firm cut surfaces with hemorrhagic and gelatinous areas and a cystic component that contains approximately 200 cc of tan-brown, mucinous fluid and comprises approximately 20% of the mass. Within the solid component, a 1.0 cm tan, fleshy, discrete nodule and a 2.0 cm, red, circumscribed nodule are identified. The serosal surface is inked black. The mass is located 3.5 from the mesocolic resection margin. Representative sections are submitted. Gross photographs are taken. Tissue is submitted for TPS.

Summary of Sections:

M1-large bowel margin
M2-large bowel margin, opposite end
TM-tumor in relation to mucosa
T-sections of tumor (1_15, and 1_16 contain inked serosa)
TN-tumor nodule
TRN-red nodule
MS-mesocolon
LN-whole lymph nodes
BLN- bisected lymph nodes

2. The specimen is received in formalin, labeled, "umbilical hernia" and consists of a piece of tan-yellow soft tissue that measures 4.4 x 3.3 x 1.2 cm. Serial sections reveal fibrous and fatty cut surfaces. Representative sections are submitted.

Summary of sections:

U -- undesignated

** Continued on next page **

[page 3 of 3]
Summary of Sections:

Part 1: Radical resection of abdominal mass with resection of splenic flexure of colon

Block	Sect. Site	PCs
5	BLN	5
3	LN	3
1	M1	1
1	M2	1
3	MS	3
24	T	24
4	TM	4
1	TN	1
2	TRN	2

Part 2: Umbilical hernia

Block	Sect. Site	PCs
1	U	1

** End of Report **

Source: NCI Genomic Data Commons file 03b7e31f-d0de-4cfb-90d0-7dd0486311c9 (TCGA-DX-A6B9.B99CC0DF-16B4-4BED-BE5D-A9AAC7196609.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).